Somatic mutation profile of tumor specimen TARGET-20-PASRSS-09A (aliquot TARGET-20-PASRSS-09A-01D) from TARGET case TARGET-20-PASRSS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (743 days).
Specimen TARGET-20-PASRSS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75b76bfa-99cb-4743-888c-5edd62932f7a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASRSS-14A (Bone Marrow Normal), aliquot TARGET-20-PASRSS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3de45ee9-ace1-4cdb-87fd-9ed33e8f2a15

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/180 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- MYC | c.1076A>G p.H359R (on ENST00000377970; = p.H374R on NM_002467.6) | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367783; called by muse, mutect2, varscan2
- RAD21 | c.9C>G p.Y3* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV52056015, COSV52057457; called by muse, mutect2, varscan2
- REV3L | c.*486A>G | 3'UTR (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
